Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7840, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7840-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

1. Adipose tissue, "over right renal mass", partial nephrectomy: Adipose tissue, no tumor seen.
2. Kidney, right, upper pole, cyst wall, partial nephrectomy: Renal parenchyma with fibrosis.
3. Kidney, right, mass/cyst, partial nephrectomy:
- Renal cell carcinoma, papillary type I.
- Renal parenchyma with cysts and fibrosis.
- Fibroadipose tissue. No tumor seen.

NOTE:

CLINICAL INFORMATION: Allocate Order to Protocol: [REDACTED] Brief Clinical History: [REDACTED]
with bilateral multifocal papillary renal tumors. [REDACTED] right robotic
partial [REDACTED] Specimen Taken For [REDACTED]

PROCEDURE: Pre-Operative Diagnosis: right renal mass Post-Operative Diagnosis:
same Operative Findings: 3cm renal mass,

Patient Identification

[page 2 of 3]
[REDACTED]

SPECIMENS SUBMITTED: 1. FAT, Over right renal mass
2. CYST, Right upper pole renal wall
3. CYST, Right renal mass

GROSS DESCRIPTION: Received are 3 freshly submitted specimens in containers labeled with patient's name, medical record number, and further specified as follows:

1. "Fat over right renal mass/cyst" is a yellow soft lobulated adipose tissue fragment, 6.4 x 2.5 x 1.3 cm. It is serially sectioned revealing yellow soft lobulated cut surfaces. Representative sections are submitted in white cassettes [REDACTED] #1A-1D.
2. "Right upper pole renal cyst wall" are multiple tan-pink cyst wall lining fragments ranging from 0.2 to 1.5 cm in greatest dimensions and in the aggregate 1.5 x 0.4 x 0.2 cm. Gross photographs are taken. No tissues are procured. The specimen is entirely placed into formalin and submitted to Pathology for permanent. In [REDACTED] the specimen matches the above description. The cyst wall lining is entirely submitted in white cassette [REDACTED] #1.
3. "Right renal mass/cyst" is a disrupted tan-pink cystic structure, 6.5 x 3 x 2.5 cm, filled with friable and hemorrhagic golden yellow-red soft tissues. Gross photographs are taken. Margins are not a concern per [REDACTED]. Approximately 50% of tissue is procured for [REDACTED]. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and entirely submitted in white cassettes [REDACTED] #3A-....

Gross description dictated by [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 3 of 3]
Patient Identification

Source: NCI Genomic Data Commons file f86c642c-2642-4b0c-b4d6-cf87241f5943 (TCGA-DW-7840.582E185E-7593-4238-A230-846ACAA0A9A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).